Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A3HV, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A3HV-01A (Primary Tumor).

Procurement Date: Laterality:

Path Report:SKIN TISSUE CHECKLIST

Specimen type: Excision of tumor

Tumor site: Skin

Tumor size: 5.5 x 4.5 x 1.3 cm

Tumor features: Raised, Pigmented

Satellite nodules: Not specified

Histologic type: Nodular melanoma

Histologic grade:

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: Clark level 4

Gross Description:

Microscopic Description:

Diagnosis Details:

ICD-0-3
Melanoma, nodular 8721/3
Site: Skin, NOS C44.9

hw 12/1/14

Case is (cin.le):	QUANIFIED	DISQUALIFIED

Source: NCI Genomic Data Commons file 1f9993ae-d01b-4927-91c0-25d4d2dc77e7 (TCGA-EB-A3HV.BA0FAD4F-F42F-4BE2-932B-A2908260130C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).